Surgical pathology report (de-identified scan), TCGA case TCGA-Y8-A8S0, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Spectrum Health, specimen TCGA-Y8-A8S0-01A (Primary Tumor).

[page 1 of 2]
Research Gross Description

male with left renal mass

ICD O-3
Carcinoma, papillary renal cell
Site @ Kidney NOS 8260/3
C64.9
JW 1/17/14

Research Dx

CASE SUMMARY FOR NEPHRECTOMY FOR RENAL CELL CARCINOMA:

Procedure: Laparoscopic partial nephrectomy

Specimen laterality: Left

Tumor site: Inferolateral cortex

Tumor size: 1 x 1 x 0.7 cm

Tumor focality: Unifocal

Macroscopic extent of tumor: Tumor limited to the kidney

Histologic type: Papillary renal cell carcinoma, type I

Sarcomatoid features: Not identified

Tumor necrosis: Not identified

Histologic grade (Fuhrman Nuclear Grade): 2

Microscopic tumor extension: Tumor limited to the kidney

Margins: Negative for carcinoma(tumor extends to within 0.5 mm of the parenchymal margin

Lymph-Vascular invasion: Not identified

Pathologic staging (pTNM):

Primary tumor: pT1a: Tumor 4 cm or less in greatest dimension, limited to the kidney

Regional lymph nodes: pNX: Unable to assess

Distant metastasis: pM: Not applicable

Pathologic findings in nonneoplastic kidney: No significant histologic abnormalities.

Other tumors and/or tumor-like lesions: None identified

AJCC Staging (7th edition) pT1a pNX pM: Not applicable

Research QC

Tumor T1:

100% tumor nuclei

0% necrosis

0% normal

Normal N1:

100% benign kidney

Research Specimen

-

Specimen Process Time

Blood draw time:

Plasma frozen time

Serum frozen time:

Buffy coat frozen time:

Tissue:

Cold ischemia start time:

Formalin fixation start time

Frozen start time:

Total cold ischemia time:

Formalin fixation stop time:

Total formalin fixation time:

[page 2 of 2]
Specimen Weight

Normal

1-112 mg

Tumor

1-135 mg_

Specimen Size

Plasma x 3

Serum x 1

Buffy coat x 1

Cryovials x 2

Normal x 1

Tumor x 1

Metastatic x 0

FFPE x 2

Normal x 1

Tumor x 1 (-no FS)

Metastatic x 0

Study

Patient Consent

Yes

Source: NCI Genomic Data Commons file 473925cb-bce9-4526-a5c9-a715aa56f071 (TCGA-Y8-A8S0.3D3C8809-0309-484B-9E1E-98A0A5613E85.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).